Somatic mutation profile of tumor specimen 0DR3MB from CCDI case PBCFSC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Tumor cells, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.0 years (723 days).
Specimen 0DR3MB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c96a93b2-d659-4430-a13a-aa1e72333d49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR3L2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/827035fd-447a-425b-8d38-2d58ea4414bb

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP5 | c.1005G>T p.M335I | Missense Mutation (SNP) | VAF 88/332 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs763647950; called by muse, mutect2, varscan2
- MOCOS | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 55/575 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs201559593; called by muse, mutect2
- RANBP10 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 233/507 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as rs751756862, COSV58156884; called by muse, mutect2, varscan2
- ZNF787 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.19155G>A p.T6385= | Silent (SNP) | VAF 112/292 reads (38%) | called by muse, mutect2, varscan2
- CLDN14 | c.-54G>A | 5'UTR (SNP) | VAF 21/39 reads (54%) | catalogued as rs886057051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
